CCDI case PBBWEL — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Thyroid gland.
https://portal.gdc.cancer.gov/cases/4e52f799-ee92-4693-87f2-8ee290b33950

Demographics
Sex at birth: female; Race: white; Vital status: Alive.

Diagnoses (1)
1. Papillary carcinoma, NOS: ICD-O-3 morphology code: 8050/3; Tissue or organ of origin: Thyroid gland; Age at diagnosis: 13.6 years (4,966 days).

Biospecimens (3 samples)
- Sample 0DJG6X: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DJG8O: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DJGDZ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
